Surgical pathology report (de-identified scan), TCGA case TCGA-B8-A54I, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-A54I-01A (Primary Tumor).

[page 1 of 3]
ICD-6-3

Carcinoma, renal cell NOS
Clear Cell type 8312/3
Site: (L) Kidney, NOS
11/26/12 JN 264.9

SURGI

Case N

Diagnosis:

A: Kidney, left, robotic laparoscopic partial nephrectomy

Laterality: unilateral; left side

Histologic tumor type/subtype: renal cell carcinoma, clear cell subtype (see comment)

Sarcomatoid features: absent

Histologic grade (if applicable): Fuhrman grade 3 of 4

Tumor size (greatest dimension): 6.7 cm in greatest dimension

Tumor focality: unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: tumor invades into, but not through capsule (microscopic); perirenal adipose tissue negative for malignancy

Gerota's fascia: negative for malignancy

Venous (large vessel): not identified

Lymphatic (small vessel): Present (A5)

Histologic assessment of surgical margins:

Renal parenchymal margin (partial nephrectomy only): - negative for

malignancy; tumor is 1 mm from the parenchymal margin

Renal capsular margin (partial nephrectomy only): - negative for malignancy;

tumor is 2 mm from the capsular margin

Paranephric adipose tissue margin (partial nephrectomy only): - negative for malignancy; tumor is 1 mm from the perinephric adipose tissue margin

Adrenal gland: not received

Lymph nodes: not received

Pathologic findings in non-neoplastic kidney: Extensive lymphoplasmacytic inflammation with numerous loose granulomata;

[page 2 of 3]
special stains for micro-organisms will be reported as an addendum

AJCC Staging: pT1b pNX

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Comment:

Immunohistochemical stains are performed on block A3 and demonstrate the tumor is diffusely positive for CD10 while being negative for CK7, CD15, CD117, and has faint positivity for racemase. While not entirely specific, this immunophenotype is consistent with renal cell carcinoma, clear cell subtype.

Clinical History:

·year-old male with a left renal mass.

Gross Description:

Received is one appropriately labeled container, additionally labeled "left renal mass." It holds an 85 gram, 7.5 x 5.1 x 4.2 cm partial nephrectomy. There is a small amount of attached perinephric fat. The parenchymal margin is inked black, and the perinephric soft tissue margin is inked blue. The specimen is sectioned to reveal a 6.7 x 4.1 x 4.1 cm variegated friable pink/tan mass expanding the renal capsule and focally abutting the black inked parenchymal margin. The surrounding cortex appears compressed and slightly distorted. The renal capsule is expanded and there is a 0.6 cm area of pale white nodularity (A6), but appears grossly intact. The small amount of attached perinephric fat is intact. Tumor is given to Tissue Procurement.

[page 3 of 3]
Representative sections are submitted of the lesion to include its relationship to the black inked parenchymal margin, blue inked capsular margin, capsule and adjacent parenchyma.

A1-2 - tumor and black inked parenchymal margin
A3 -tumor, capsule, perinephric fat
A4 -tumor and blue inked perinephric fat margin
A5 -tumor and fat
A6 -tumor and capsular nodule

Addendum

The purpose of this addendum is to report the results of special stains for microorganisms.

Addendum Comment

Special stains for microorganisms performed on block A2 (GMS and AFB) are negative. The original diagnoses are unchanged. The differential diagnosis for the numerous granulomata includes sarcoidosis.

Source: NCI Genomic Data Commons file 3a410a70-f631-4931-86fc-1bb5c655ef08 (TCGA-B8-A54I.69939C41-9B4D-4B4B-973F-BB184AB6ADBD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).